Gene-level copy-number profile of tumor specimen TCGA-24-1928-01A from TCGA case TCGA-24-1928, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.0 years (28,126 days).
Specimen TCGA-24-1928-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3fbc2630-ca7b-44f2-b331-bcf6dfbf6982.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1928-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe84cf2f-87a3-4065-ad44-e82d61753dd4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,549; copy number 2: 7,506; copy number 3: 17,896; copy number 4: 27,155; copy number 5: 2,136; copy number 6: 1,904; copy number 7: 5; copy number 8: 959; copy number 9: 186; copy number 10: 192; copy number 11: 11; copy number 12: 83; copy number 13: 27; copy number 14: 11; copy number 15: 4; copy number 17: 16; copy number 19: 2; copy number 22: 42; copy number 24: 1; copy number 25: 98; copy number 49: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1928-01): tumor purity 0.66, ploidy 3.56, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 704 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:71,741,696–76,283,783, 83 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:120,380,761–132,675,592, 178 genes, copy number 9–14 (broad region; genes not listed).
- chr10:52,852,607–53,766,614, 7 genes, copy number 12: Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:61,662,929–65,880,289, 43 genes, copy number 11–49 (within-gene range 3–49): CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr10:74,821,610–76,560,168, 28 genes, copy number 9–13 (within-gene range 3–13): AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1.
- chr10:76,242,022–79,982,614, 71 genes, copy number 9–22 (broad region; genes not listed).
- chr15:29,120,254–29,570,723, 1 gene, copy number 25 (within-gene range 4–25): FAM189A1.
- chr15:29,373,602–32,500,346, 97 genes, copy number 25 (broad region; genes not listed).
- chr18:27,335,968–27,595,164, 1 gene, copy number 10 (within-gene range 7–10): AC090403.1.
- chr18:27,452,514–29,650,440, 14 genes, copy number 10–19: PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr18:30,298,910–30,298,960, 1 gene, copy number 19: MIR302F.
- chr18:31,058,840–32,470,882, 43 genes, copy number 12 (within-gene range 2–12): DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2.
- chr22:34,191,194–38,273,010, 137 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
